TARGET case TARGET-10-PARIPA — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e3a51604-1172-53f9-8987-b44936635c58

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 2 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 2.7 years (968 days); Year of diagnosis: 2007; Days to last follow up: 3,115 days (8.5 years).
   Treatment given: Protocol identifier: AALL0331.

Follow-up (1 entry)
- Days to follow up: 3,115 days (8.5 years); Event-free: no event (relapse, second malignancy or death) recorded through day 3,115; Year of follow up: 2016.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 32.5 ×10³/µL.
- Day 8: Bone Marrow blast count 6%; Minimal Residual Disease (Flow Cytometry) 0.2%.
- Day 15: Bone Marrow blast count 1%.
- Day 29: Bone Marrow blast count 0%; Minimal Residual Disease (Flow Cytometry) 0%.

Biospecimens (12 samples)
- Sample TARGET-10-PARIPA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PARIPA-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.
- Samples TARGET-10-PARIPA-60.11C, TARGET-10-PARIPA-60.13C, TARGET-10-PARIPA-60.16C, TARGET-10-PARIPA-60.17C, TARGET-10-PARIPA-60.21C, TARGET-10-PARIPA-60.23C, TARGET-10-PARIPA-60.3C, TARGET-10-PARIPA-60.5C, TARGET-10-PARIPA-60.7C, TARGET-10-PARIPA-60.9C (10 with the same recorded description): Sample type: Primary Xenograft Tissue; Tissue type: Tumor; Tumor descriptor: Xenograft.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Xenografts_20230727.xlsx:
- Overall Survival Time in Days: 3115
- WBC at Diagnosis: 32.5
- CNS Status at Diagnosis: CNS 1
- MRD Day 8: 0.2
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 0
- MRD Day 29 Sensitivity: 0.001
- Bone Marrow Site of Relapse: No
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 6
- BMA Blasts Day 15: 1
- BMA Blasts Day 29: 0
- Karyotype: 25,X,+14,+21[6]/50,idem,x2[7]/46,XX[7]
- Down Syndrome: No
- DNA Index: 0.525
- Alternate Therapy: Transplant
- Cell of Origin: B Cell ALL
